Somatic mutation profile of tumor specimen TCGA-CM-6171-01A (aliquot TCGA-CM-6171-01A-11D-1650-10) from TCGA case TCGA-CM-6171, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 77.5 years (28,307 days).
Specimen TCGA-CM-6171-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d17ceb1-e774-491e-908a-749f96d31237.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6171-10A (Blood Derived Normal), aliquot TCGA-CM-6171-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e88475a-4ded-40ea-89aa-eb035fef3791

The open-access MAF lists 1,443 somatic variants for this specimen: 1,083 protein-altering or splice-affecting, 325 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 764, Silent 325, Frame Shift Del 194, Frame Shift Ins 48, Nonsense Mutation 38, Splice Site 17, In Frame Del 16, Intron 14, RNA 9, 3'UTR 4, Splice Region 4, 5'UTR 3.

Variants (750 of 1,443; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CASK | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 177/399 reads (44%) | catalogued as rs387906704, CM118654, COSV59376402; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.4405C>T p.R1469C | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587782946, CD063528, COSV100355152; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ITGA2B | c.3076C>T p.R1026W | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766503255, CM113241, COSV52231603; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.4549C>T p.R1517* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as rs1459799356, COSV55860009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.1489del p.R497Gfs*11 | Frame Shift Del (DEL) | VAF 54/183 reads (30%) | catalogued as rs63750855, COSV51623024; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 44/121 reads (36%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 108/288 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RIN2 | c.1878dup p.I627Hfs*7 (on ENST00000255006 / NM_001242581.1; = p.I578Hfs*7 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 54/124 reads (44%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, varscan2
- SCN1A | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 126/382 reads (33%) | catalogued as rs1064796824, COSV57690630; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SIN3A | c.3310C>T p.R1104* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as rs879255621, COSV64581642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 81/219 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1568C>T p.T523I | Missense Mutation (SNP) | VAF 178/468 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV100229496, COSV55299522; called by muse, mutect2, varscan2
- AAAS | c.771del p.R258Gfs*33 | Frame Shift Del (DEL) | VAF 64/168 reads (38%) | catalogued as rs1184877278, CD067140; called by mutect2, pindel
- AARD | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375266231, COSV65599577, COSV65600510; called by muse, mutect2, varscan2
- ABCA3 | c.4354G>A p.G1452R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs375783245, COSV57058889; called by muse, mutect2, varscan2
- ABCA3 | c.2573A>G p.Q858R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV57060859; called by muse, mutect2
- ABCA6 | c.1033A>G p.T345A | Missense Mutation (SNP) | VAF 126/294 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.119); catalogued as rs1398920141, COSV52645932; called by muse, mutect2
- ABCA7 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as rs139415355; called by muse, mutect2, varscan2
- ABCB1 | c.1292G>A p.C431Y | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55965044; called by muse, mutect2, varscan2
- ABCC1 | c.2794G>A p.A932T | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs768011444, COSV60695411; called by muse, mutect2, varscan2
- ABCG4 | c.1019G>T p.S340I | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV100266783; called by muse, mutect2, varscan2
- ABHD10 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs145014452, COSV56326586; called by muse, mutect2, varscan2
- ABL1 | c.3106A>G p.T1036A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.057); catalogued as COSV100584031; called by muse, mutect2
- ABO | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.043); catalogued as COSV101505945, COSV101505960; called by muse, mutect2, varscan2
- AC011462.1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1052314774, COSV99524589; called by muse, mutect2, varscan2
- AC231657.3 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV59877112; called by muse, mutect2, varscan2
- ACAP1 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1323809366, COSV50142943; called by muse, mutect2, varscan2
- ACE | c.3682C>T p.P1228S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs967933744, COSV52005278; called by muse, mutect2, varscan2
- ACLY | c.2954T>C p.M985T | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV59863249; called by muse, mutect2
- ACOT2 | c.46A>G p.R16G | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs765220557, COSV53151793; called by muse, mutect2, varscan2
- ACP2 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs757664236, COSV57044193; called by muse, mutect2, varscan2
- ACSF3 | c.545C>A p.P182Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV58082313; called by muse, mutect2, varscan2
- ACSL5 | c.1525G>A p.E509K (on ENST00000354273; = p.E565K on NM_016234.3) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as rs1564744137, COSV61133867; called by muse, mutect2, varscan2
- ACYP1 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 122/304 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173132014, COSV53136111; called by muse, varscan2
- ADA | c.66C>G p.I22M | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV65740948; called by muse, mutect2, varscan2
- ADAMTS15 | c.2453C>A p.P818H | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV100143400; called by muse, mutect2, varscan2
- ADCY1 | c.2704G>A p.A902T | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52029776; called by muse, mutect2, varscan2
- ADCY7 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99576035; called by muse, mutect2, varscan2
- ADGRA2 | c.1840G>A p.V614M | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs757708388, COSV59447812; called by muse, mutect2, varscan2
- ADGRB2 | c.3421del p.L1141Cfs*35 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as COSV57072776, COSV57073898; called by mutect2, pindel, varscan2
- ADGRB2 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs774342144, COSV99926292; called by muse, mutect2, varscan2
- ADGRF1 | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 75/86 reads (87%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV64801313; called by muse, mutect2, varscan2
- ADGRV1 | c.6382C>T p.R2128* | Nonsense Mutation (SNP) | VAF 75/170 reads (44%) | catalogued as rs727504561, CM1510634, COSV101316083, COSV67996577; called by muse, mutect2, varscan2
- ADI1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772279164, COSV59376584; called by muse, mutect2, varscan2
- ADPGK | c.365T>C p.F122S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as COSV61175350; called by muse, mutect2, varscan2
- ADRA2B | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101337398, COSV69787824; called by muse, mutect2, varscan2
- AGL | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.074); catalogued as COSV99649258; called by muse, mutect2, varscan2
- AGO4 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs769017079, COSV100942964; called by muse, mutect2, varscan2
- AGXT2 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 127/311 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV51491395; called by muse, mutect2, varscan2
- AHCY | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV54154682; called by muse, mutect2, varscan2
- AJUBA | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV52985750, COSV52986912; called by muse, mutect2, varscan2
- AKAP13 | c.5063C>G p.S1688C (on ENST00000394518 / NM_007200.5; = p.S1692C on NM_006738.6) | Missense Mutation (SNP) | VAF 41/691 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100773836; called by muse, mutect2
- AKAP6 | c.5738C>A p.T1913N | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV55235680; called by muse, mutect2, varscan2
- AKAP8 | c.512G>A p.S171N | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99511934; called by muse, mutect2
- ALDH16A1 | c.1039del p.A347Lfs*155 | Frame Shift Del (DEL) | VAF 38/136 reads (28%) | catalogued as rs1368010977; called by mutect2, pindel
- ALKBH7 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55532717; called by muse, varscan2
- ALOX5 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs767991624, COSV65554890; called by muse, mutect2, varscan2
- AMBRA1 | c.1678C>A p.L560M (on ENST00000458649 / NM_001367468.1; = p.L470M on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV54063567; called by muse, mutect2, varscan2
- AMDHD1 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.345); catalogued as COSV57140691; called by muse, mutect2, varscan2
- ANGPTL1 | c.151T>C p.Y51H | Missense Mutation (SNP) | VAF 137/880 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368423; called by muse, mutect2, varscan2
- ANK1 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs150284251; called by muse, mutect2, varscan2
- ANKRD11 | c.3686C>T p.T1229M | Missense Mutation (SNP) | VAF 143/372 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs775494693, COSV56373570; called by muse, mutect2, varscan2
- ANKRD11 | c.3341A>G p.Y1114C | Missense Mutation (SNP) | VAF 121/324 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56373579; called by muse, mutect2, varscan2
- ANKRD2 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV53969905; called by muse, mutect2, varscan2
- ANKRD50 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as rs377077898; called by muse, mutect2, varscan2
- ANO7 | c.1879C>T p.R627C (on ENST00000274979; = p.R573C on NM_001370694.2) | Missense Mutation (SNP) | VAF 101/267 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144795528; called by muse, varscan2
- ANO8 | c.1087del p.L363Cfs*24 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as COSV50178856; called by mutect2, pindel, varscan2
- AP1G1 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs781714640, COSV55496031; called by muse, mutect2, varscan2
- AP1G2 | c.1345del p.A449Pfs*84 | Frame Shift Del (DEL) | VAF 29/80 reads (36%) | catalogued as rs749982998; called by mutect2, varscan2
- AP2B1 | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs761350585, COSV52004042; called by muse, mutect2, varscan2
- AP4M1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.406); catalogued as rs757649099, COSV57999393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APPBP2 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 118/305 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV50026312; called by muse, mutect2, varscan2
- AR | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.997); catalogued as rs1158367061, COSV65964601; called by muse, mutect2, varscan2
- ARAF | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754787460, COSV99283195; called by muse, mutect2, varscan2
- ARAP3 | c.4409dup p.S1471Ffs*82 | Frame Shift Ins (INS) | VAF 39/89 reads (44%) | catalogued as rs1308620191; called by mutect2, pindel, varscan2
- ARFRP1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.616); catalogued as rs972592890, COSV53929468; called by muse, mutect2, varscan2
- ARHGAP10 | c.1936C>A p.P646T | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as COSV100331260; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 93/258 reads (36%) | catalogued as rs773922861; called by mutect2, varscan2
- ARHGAP22 | c.1702C>T p.H568Y | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1193036524, COSV50996081; called by muse, mutect2, varscan2
- ARHGEF17 | c.3032del p.M1011Sfs*2 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as COSV55239033; called by mutect2, pindel, varscan2
- ARHGEF40 | c.1199T>C p.L400P | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); catalogued as COSV53884847; called by muse, mutect2
- ARID1B | c.2165del p.P722Hfs*10 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as COSV99272954; called by mutect2, pindel, varscan2
- ARID1B | c.4196C>T p.S1399L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as rs781209005, COSV51683258; called by muse, mutect2, varscan2
- ARMH3 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); catalogued as COSV64238570; called by muse, mutect2, varscan2
- ASAP2 | c.2357dup p.L787Afs*16 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | catalogued as rs773893016; called by mutect2, varscan2
- ASB15 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 102/225 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754308297, COSV51929740; called by muse, mutect2, varscan2
- ASIC1 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99948080; called by muse, mutect2, varscan2
- ASMTL | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs371685612, COSV67245305; called by muse, mutect2, varscan2
- ASPM | c.1573G>T p.V525L | Missense Mutation (SNP) | VAF 508/1222 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV54139999; called by muse, mutect2, varscan2
- ASXL3 | c.5809G>A p.A1937T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as rs763596943, COSV52481583; called by muse, mutect2, varscan2
- ATAD2B | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 136/377 reads (36%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.964); catalogued as COSV53206489; called by muse, mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 46/116 reads (40%) | catalogued as rs1558707706; called by mutect2, varscan2
- ATG2B | c.1975-2del p.X659_splice | Splice Site (DEL) | VAF 4/34 reads (12%) | catalogued as rs1182195036, COSV63427022; called by pindel, varscan2
- ATG7 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1370064286, COSV56074670; called by muse, mutect2, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 38/96 reads (40%) | catalogued as rs764067652, COSV56705401; called by mutect2, varscan2
- ATP2B3 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1557015441, COSV54843187, COSV54863460; called by muse, mutect2, varscan2
- ATP6V0D2 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs774964031, COSV53413041; called by muse, mutect2, varscan2
- ATP6V0E2 | c.230G>A p.R77H (on ENST00000425642; = p.R126H on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs765329489, COSV70416394; called by muse, mutect2, varscan2
- ATP8B2 | c.646A>G p.T216A (on ENST00000672630; = p.T183A on NM_001005855.2) | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59249483; called by muse, mutect2
- AUTS2 | c.1047G>T p.Q349H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.748); catalogued as COSV61424309, COSV61432694; called by muse, mutect2, varscan2
- AWAT2 | c.447C>A p.F149L | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.023); catalogued as COSV52142722, COSV52144805; called by muse, mutect2, varscan2
- B3GNTL1 | c.82A>G p.N28D | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57954541; called by muse, mutect2, varscan2
- B4GALT2 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs753720865, COSV58844797; called by muse, mutect2, varscan2
- BAHCC1 | c.2959C>A p.P987T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs1421906103, COSV57034180; called by muse, mutect2, varscan2
- BARHL1 | c.702G>C p.K234N | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55039113; called by muse, mutect2, varscan2
- BAZ2A | c.3119G>A p.R1040Q | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs753771866, COSV51644695; called by muse, mutect2, varscan2
- BCDIN3D | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV61702913; called by muse, mutect2, varscan2
- BCKDK | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as COSV54894218; called by muse, mutect2, varscan2
- BCL11A | c.1889C>T p.A630V (on ENST00000335712 / NM_001365609.1; = p.A664V on NM_018014.4) | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59631317; called by muse, mutect2, varscan2
- BDP1 | c.7279G>T p.G2427* | Nonsense Mutation (SNP) | VAF 66/152 reads (43%) | catalogued as COSV100703099; called by muse, varscan2
- BEND3 | c.1152C>A p.S384R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.23); catalogued as COSV64682477; called by muse, mutect2, varscan2
- BHLHE22 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58863271; called by muse, mutect2, varscan2
- BICDL1 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.466); catalogued as COSV66909122; called by muse, mutect2, varscan2
- BICRAL | c.1867T>C p.S623P | Missense Mutation (SNP) | VAF 89/130 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV58408792; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1730T>C p.F577S | Missense Mutation (SNP) | VAF 199/544 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV63247704; called by muse, mutect2, varscan2
- BOC | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs764634173, COSV56358734; called by muse, mutect2, varscan2
- BPIFB6 | c.846+1G>A p.X282_splice | Splice Site (SNP) | VAF 92/189 reads (49%) | catalogued as rs1261435145, COSV62756867; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD4 | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99650714; called by muse, mutect2, varscan2
- BRD4 | c.2446G>A p.V816I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as rs760576705, COSV54596037; called by muse, mutect2, varscan2
- BRD8 | c.1592C>G p.A531G (on ENST00000254900 / NM_139199.2; = p.A604G on NM_006696.4) | Missense Mutation (SNP) | VAF 153/333 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV50172389; called by muse, mutect2, varscan2
- BRINP3 | c.1214A>C p.Q405P | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100818811; called by muse, mutect2
- BTBD7 | c.638G>T p.R213M | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV100108042; called by muse, mutect2, varscan2
- C10orf88 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.764); catalogued as COSV64404519; called by muse, mutect2, varscan2
- C11orf87 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.96); catalogued as COSV100535802; called by muse, mutect2, varscan2
- C17orf98 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766541161; called by muse, mutect2, varscan2
- C2CD3 | c.5336G>A p.R1779H | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs142169110; called by muse, mutect2, varscan2
- C4orf50 | c.491G>A p.S164N (on ENST00000324058; = p.S1396N on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.638); catalogued as COSV100135881, COSV60688599; called by muse, mutect2, varscan2
- C6orf15 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 59/74 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1331420225, COSV52538723; called by muse, mutect2, varscan2
- C7orf50 | c.535del p.L179Cfs*136 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs750339990; called by mutect2, pindel, varscan2
- CACHD1 | c.3704dup p.Q1236Sfs*23 | Frame Shift Ins (INS) | VAF 40/118 reads (34%) | catalogued as rs764948820; called by mutect2, varscan2
- CACNA1C | c.1658C>T p.T553I | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59779254; called by muse, mutect2, varscan2
- CACNA1G | c.3619C>T p.R1207C | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs775810943, COSV100661719, COSV61741215; called by muse, mutect2, varscan2
- CACNA1H | c.4712G>A p.R1571Q | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs752887237, COSV61991764, COSV62005829; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 69/193 reads (36%) | catalogued as rs1375954479; called by mutect2, varscan2
- CAMTA2 | c.2597dup p.A867Cfs*7 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | catalogued as rs745547658; called by mutect2, varscan2
- CARD9 | c.1437C>T p.D479= | Splice Region (SNP) | VAF 8/15 reads (53%) | catalogued as COSV52518298; called by muse, mutect2, varscan2
- CARS2 | c.1011del p.D338Mfs*44 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs1566653787; called by mutect2, pindel, varscan2
- CASZ1 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470591711, COSV59739493; called by muse, mutect2, varscan2
- CATSPER1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs754843613, COSV56409554; called by muse, mutect2, varscan2
- CBLN3 | c.174dup p.P59Afs*25 | Frame Shift Ins (INS) | VAF 27/92 reads (29%) | catalogued as rs1385647942; called by mutect2, pindel, varscan2
- CBX8 | c.942del p.S315Afs*41 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs755669870; called by mutect2, pindel, varscan2
- CCDC120 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs782349834, COSV64481865; called by muse, mutect2, varscan2
- CCDC158 | c.2870G>T p.R957I | Missense Mutation (SNP) | VAF 228/656 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.203); catalogued as COSV66357336; called by muse, mutect2, varscan2
- CCDC180 | c.4069C>T p.R1357C | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760603808, COSV63836101; called by muse, mutect2, varscan2
- CCDC50 | c.1016C>T p.P339L (on ENST00000392455 / NM_178335.3; = p.P163L on NM_174908.4) | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.294); catalogued as COSV101165267, COSV66669950; called by muse, varscan2
- CCDC78 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs369344548, COSV52400793; called by muse, mutect2, varscan2
- CCDC93 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs779574804, COSV60119365; called by muse, mutect2, varscan2
- CCL24 | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV56116656; called by muse, mutect2, varscan2
- CCL26 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50013826; called by muse, mutect2, varscan2
- CCNA1 | c.814C>A p.L272M | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV55224556; called by muse, mutect2, varscan2
- CCT8L2 | c.1168C>A p.Q390K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100742774; called by muse, mutect2, varscan2
- CDH13 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV99226398; called by muse, mutect2, varscan2
- CDH24 | c.714dup p.L239Afs*67 | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | catalogued as rs765496989; called by mutect2, varscan2
- CDH6 | c.463A>G p.N155D | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54079461; called by muse, mutect2, varscan2
- CDYL2 | c.354del p.Y120Ifs*27 | Frame Shift Del (DEL) | VAF 52/127 reads (41%) | catalogued as COSV101629564; called by mutect2, varscan2
- CECR2 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 52/119 reads (44%) | catalogued as rs1000953634, COSV52847831; called by muse, mutect2, varscan2
- CECR2 | c.2902G>A p.E968K (on ENST00000342247 / NM_001290047.2; = p.E785K on NM_001290046.1) | Missense Mutation (SNP) | VAF 19/387 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.193); catalogued as rs1250155010, COSV52851421; called by muse, mutect2
- CEL | c.851C>T p.T284I (on ENST00000673714; = p.T281I on NM_001807.6) | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.509); catalogued as COSV60829944; called by muse, mutect2, varscan2
- CELSR3 | c.436G>T p.G146* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV51167777; called by muse, mutect2, varscan2
- CEP131 | c.2782C>T p.R928C (on ENST00000269392 / NM_001319228.2; = p.R925C on NM_014984.4) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753513530, COSV53956858; called by muse, mutect2, varscan2
- CEP57 | c.785del p.K262Rfs*31 | Frame Shift Del (DEL) | VAF 102/252 reads (40%) | catalogued as rs762013265, COSV57689966; called by mutect2, varscan2
- CEP78 | c.133T>C p.F45L | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV52850820; called by muse, mutect2, varscan2
- CFAP44 | c.1657A>T p.I553F | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV55616328; called by muse, mutect2, varscan2
- CFH | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 221/603 reads (37%) | catalogued as COSV66406684, COSV66414279; called by muse, mutect2, varscan2
- CGB1 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs377262139; called by muse, mutect2, varscan2
- CHIT1 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55150184; called by muse, mutect2, varscan2
- CHRNG | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs752137444, COSV67315355; called by muse, mutect2, varscan2
- CIC | c.3157G>A p.V1053M | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs773634795, COSV50676816; called by muse, mutect2, varscan2
- CILP | c.2489G>T p.G830V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56028417; called by muse, mutect2, varscan2
- CLCA1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 143/315 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.23); catalogued as rs371482526; called by muse, mutect2, varscan2
- CLCN7 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325736301, COSV51974540; called by muse, mutect2, varscan2
- CLIP1 | c.3646del p.R1216Efs*6 (on ENST00000620786 / NM_001247997.1; = p.R1205Efs*6 on NM_002956.2) | Frame Shift Del (DEL) | VAF 62/156 reads (40%) | catalogued as rs761972338; called by mutect2, pindel, varscan2
- CLIP2 | c.42del p.K15Sfs*73 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as COSV56275983; called by mutect2, pindel, varscan2
- CNDP2 | c.215G>A p.G72D | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100159117; called by muse, mutect2, varscan2
- CNN2 | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.325); catalogued as COSV54038272; called by muse, mutect2, varscan2
- CNOT4 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs371838377; called by muse, mutect2, varscan2
- CNTN2 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs764275222, COSV59352121; called by muse, mutect2, varscan2
- CNTN5 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 98/276 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54344302, COSV99677154; called by muse, varscan2
- COL11A1 | c.1042T>G p.Y348D | Missense Mutation (SNP) | VAF 125/327 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV62200052; called by muse, mutect2, varscan2
- COL11A1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs754339349, COSV62200062; called by muse, varscan2
- COL17A1 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1460608787, COSV100793176; called by muse, mutect2, varscan2
- COL24A1 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 148/446 reads (33%) | catalogued as COSV65315259; called by muse, mutect2, varscan2
- COL28A1 | c.2797G>T p.G933W | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101258936, COSV68085130; called by muse, mutect2
- COL28A1 | c.1417G>T p.G473* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as COSV68085131; called by muse, mutect2, varscan2
- COL6A3 | c.5623G>A p.V1875I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55113114; called by muse, mutect2, varscan2
- COL7A1 | c.1131G>T p.Q377H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as COSV60404067; called by muse, mutect2, varscan2
- COPB2 | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1409892293, COSV100300663; called by muse, mutect2, varscan2
- COQ4 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200009624, COSV55958190; called by muse, mutect2, varscan2
- CR2 | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65510041; called by muse, mutect2, varscan2
- CRACDL | c.735G>A p.S245= | Splice Region (SNP) | VAF 26/59 reads (44%) | catalogued as rs1003454801, COSV67410385; called by muse, mutect2, varscan2
- CREBBP | c.4213G>A p.V1405M | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140133512, COSV52142608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYBA1 | c.272_274del p.G91del | In Frame Del (DEL) | VAF 114/267 reads (43%) | catalogued as rs1064797219; called by pindel, varscan2
- CRYBG1 | c.2422A>G p.K808E | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.012); catalogued as COSV64814968; called by muse, mutect2, varscan2
- CRYBG3 | c.7574+2T>C p.X2525_splice | Splice Site (SNP) | VAF 268/674 reads (40%) | catalogued as COSV99477023; called by muse, mutect2
- CRYGN | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs373827604, COSV61563401; called by muse, mutect2, varscan2
- CSRP2 | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 229/532 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60703667; called by muse, varscan2
- CTCFL | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 125/299 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429635968, COSV54778791; called by muse, mutect2, varscan2
- CTIF | c.659A>G p.N220S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV56492765; called by muse, mutect2, varscan2
- CUX1 | c.1369G>A p.D457N (on ENST00000437600 / NM_181500.4; = p.D459N on NM_001913.5) | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.951); catalogued as rs781847411, COSV52947962; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP17A1 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371825363, HM0669; called by muse, mutect2, varscan2
- CYP17A1 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.426); catalogued as COSV64005176; called by muse, mutect2, varscan2
- CYP3A5 | c.166-1G>T p.X56_splice | Splice Site (SNP) | VAF 16/136 reads (12%) | catalogued as COSV56122804, COSV56123474; called by muse, mutect2, varscan2
- CYP4F11 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs138578304; called by muse, mutect2, varscan2
- CYP4V2 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs142136741; called by muse, mutect2, varscan2
- DAB1 | c.1385G>A p.R462H (on ENST00000371231; = p.R429H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs144347021, COSV64692596; called by muse, mutect2, varscan2
- DAPK1 | c.3822dup p.Y1275Vfs*64 | Frame Shift Ins (INS) | VAF 20/48 reads (42%) | catalogued as rs779681511; called by mutect2, varscan2
- DBF4B | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV59262335; called by muse, mutect2, varscan2
- DCAF4L2 | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.216); catalogued as COSV100150914; called by muse, mutect2, varscan2
- DCDC1 | c.90A>T p.Q30H | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV60860823; called by muse, mutect2, varscan2
- DCDC2B | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | catalogued as rs1277508368, COSV52211578; called by muse, mutect2, varscan2
- DCST1 | c.758A>G p.N253S | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55063937; called by muse, mutect2, varscan2
- DCUN1D3 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60955109; called by muse, mutect2, varscan2
- DDIT3 | c.314_323del p.R105Lfs*13 | Frame Shift Del (DEL) | VAF 62/167 reads (37%) | catalogued as COSV56259190; called by mutect2, pindel, varscan2
- DDX18 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 105/234 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99604552; called by muse, varscan2
- DDX43 | c.1092del p.G365Vfs*2 | Frame Shift Del (DEL) | VAF 131/416 reads (31%) | catalogued as rs1424884917, COSV64836411; called by mutect2, pindel, varscan2
- DDX58 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 132/371 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs759405155, COSV65885070; called by muse, mutect2, varscan2
- DEF6 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769622016, COSV57355613; called by muse, mutect2, varscan2
- DENND4A | c.3313T>C p.F1105L | Missense Mutation (SNP) | VAF 99/261 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV71267142; called by muse, mutect2, varscan2
- DEPDC1 | c.1039_1041del p.L347del | In Frame Del (DEL) | VAF 238/594 reads (40%) | catalogued as COSV63959446; called by pindel, varscan2
- DEPDC5 | c.2018C>T p.A673V (on ENST00000400246; = p.A742V on NM_014662.5) | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56712245; called by muse, mutect2, varscan2
- DGKA | c.1810A>G p.S604G | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59389019; called by muse, mutect2, varscan2
- DGKD | c.1059C>G p.D353E (on ENST00000264057 / NM_152879.3; = p.D309E on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51114017; called by muse, mutect2, varscan2
- DHX15 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV61026804; called by muse, mutect2, varscan2
- DHX34 | c.1144_1146del p.L382del | In Frame Del (DEL) | VAF 11/24 reads (46%) | catalogued as rs1411109202; called by pindel, varscan2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs771360300; called by mutect2, varscan2
- DIDO1 | c.5812C>T p.R1938W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs773773031, COSV56635189; called by muse, mutect2, varscan2
- DIDO1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56635200; called by muse, mutect2, varscan2
- DIP2C | c.3169G>A p.V1057I | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.206); catalogued as rs1016127296, COSV55181632; called by muse, mutect2, varscan2
- DISP1 | c.4436_4438del p.N1479_S1480delinsT | In Frame Del (DEL) | VAF 109/323 reads (34%) | catalogued as COSV52665817; called by mutect2, pindel, varscan2
- DISP3 | c.3448C>T p.Q1150* | Nonsense Mutation (SNP) | VAF 52/148 reads (35%) | catalogued as COSV99608698; called by muse, mutect2, varscan2
- DKC1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs782010351, COSV65777217; called by muse, mutect2, varscan2
- DKK3 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs756280059, COSV58869250; called by muse, mutect2, varscan2
- DLG1 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58392523; called by muse, mutect2, varscan2
- DLG2 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 42/97 reads (43%) | catalogued as COSV54689884; called by muse, mutect2, varscan2
- DLG5 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1168266363, COSV64950254; called by muse, mutect2, varscan2
- DNAAF3 | c.742T>C p.Y248H (on ENST00000524407 / NM_001256715.2; = p.Y295H on NM_178837.4) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs1196723858, COSV61279811; called by muse, mutect2, varscan2
- DNAH1 | c.10747T>G p.F3583V | Missense Mutation (SNP) | VAF 104/233 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV70237338; called by muse, mutect2
- DNAH10 | c.10249G>A p.A3417T (on ENST00000409039; = p.A3356T on NM_207437.3) | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs373563169; called by muse, mutect2, varscan2
- DNAH5 | c.877del p.R293Dfs*12 | Frame Shift Del (DEL) | VAF 56/201 reads (28%) | catalogued as COSV54201852; called by mutect2, pindel, varscan2
- DNAH9 | c.10596del p.G3533Dfs*40 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | catalogued as COSV52345258; called by mutect2, varscan2
- DNAJB5 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs543819950, COSV56625102; called by muse, mutect2, varscan2
- DNAJC6 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs141779215; called by muse, mutect2, varscan2
- DNHD1 | c.13934C>T p.T4645M | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as rs768306941, COSV54444147; called by muse, mutect2, varscan2
- DNMT3A | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 95/264 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs200845575; called by muse, mutect2, varscan2
- DOCK1 | c.4624G>A p.E1542K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1373864109, COSV54738384; called by muse, mutect2, varscan2
- DOCK1 | c.4705G>T p.A1569S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs912863246, COSV54762736; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 127/242 reads (52%) | catalogued as rs782552436; called by pindel, varscan2
- DOCK7 | c.6354G>T p.K2118N (on ENST00000635253 / NM_001367561.1; = p.K2087N on NM_033407.3) | Missense Mutation (SNP) | VAF 167/387 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV99224535; called by muse, mutect2, varscan2
- DPH5 | c.272A>G p.H91R | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100587401; called by muse, mutect2
- DPM1 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.163); catalogued as COSV54868131; called by muse, mutect2, varscan2
- DSCAM | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs776863787, COSV68037674; called by muse, mutect2, varscan2
- DTNA | c.268del p.Y90Tfs*47 | Frame Shift Del (DEL) | VAF 94/236 reads (40%) | catalogued as COSV51997228; called by mutect2, pindel, varscan2
- DYNC1H1 | c.9572G>A p.R3191Q | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1280908648, COSV64143612; called by muse, mutect2, varscan2
- DYNC1H1 | c.12368G>A p.R4123Q | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64143619; called by muse, mutect2, varscan2
- DZIP1L | c.1525A>G p.R509G | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100551383; called by muse, mutect2
- EDEM1 | c.752T>C p.M251T | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV56584536; called by muse, mutect2
- EEF1AKNMT | c.1099C>A p.P367T (on ENST00000361735 / NM_015935.5; = p.P281T on NM_014955.3) | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.496); catalogued as COSV100675874; called by muse, mutect2, varscan2
- EFCAB5 | c.2529del p.F843Lfs*13 | Frame Shift Del (DEL) | VAF 47/122 reads (39%) | catalogued as rs1236463784; called by mutect2, pindel, varscan2
- EGF | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99490946; called by muse, varscan2
- EHD3 | c.1535T>C p.L512P | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100434732; called by muse, mutect2
- ELAPOR1 | c.1220-1G>T p.X407_splice | Splice Site (SNP) | VAF 31/81 reads (38%) | catalogued as rs201736508, COSV64041379; called by muse, mutect2, varscan2
- ELMO1 | c.1853C>T p.T618M | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as rs775714420, COSV60327753; called by muse, mutect2, varscan2
- ELP5 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1282040717, COSV100021013; called by muse, mutect2, varscan2
- EMC7 | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 40/92 reads (43%) | catalogued as COSV56629463; called by muse, mutect2, varscan2
- ENC1 | c.1041del p.R348Gfs*39 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as COSV100188076; called by mutect2, pindel
- ENC1 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56631574; called by muse, mutect2, varscan2
- ENGASE | c.1638del p.T547Pfs*14 | Frame Shift Del (DEL) | VAF 112/310 reads (36%) | catalogued as rs759157900, COSV56136050; called by mutect2, pindel, varscan2
- ENO3 | c.1099del p.V367* | Frame Shift Del (DEL) | VAF 38/161 reads (24%) | catalogued as rs961001512; called by mutect2, pindel, varscan2
- EOMES | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.972); catalogued as rs761569819, COSV55412554; called by muse, mutect2, varscan2
- EPHA3 | c.995T>C p.V332A | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.253); catalogued as COSV60730225; called by muse, mutect2, varscan2
- EPHA3 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60692736, COSV60699595; called by muse, mutect2, varscan2
- EPHA6 | c.548C>A p.T183K | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67595991; called by muse, mutect2, varscan2
- EPS8L3 | c.1640C>T p.T547M (on ENST00000361965 / NM_133181.4; = p.T517M on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100719716; called by muse, mutect2, varscan2
- ERBB2 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54084470; called by muse, mutect2, varscan2
- ERCC2 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs939705286, COSV55545251; called by muse, mutect2, varscan2
- ESX1 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 121/274 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV65424685; called by muse, mutect2, varscan2
- ESYT3 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs752923089, COSV56679696; called by muse, mutect2, varscan2
- ETFA | c.562+1G>A p.X188_splice | Splice Site (SNP) | VAF 109/314 reads (35%) | catalogued as COSV51212499; called by muse, mutect2, varscan2
- EVC2 | c.335C>A p.P112Q | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100186023; called by muse, mutect2, varscan2
- EWSR1 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as COSV58428320; called by muse, mutect2, varscan2
- EZHIP | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.295); catalogued as rs782463147, COSV57955105; called by muse, mutect2, varscan2
- FAM126A | c.896G>T p.R299M | Missense Mutation (SNP) | VAF 201/470 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); catalogued as COSV69472702; called by muse, mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 38/93 reads (41%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM160B2 | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs547050984, COSV99249013; called by muse, mutect2, varscan2
- FAM222B | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57934872; called by muse, mutect2, varscan2
- FAM78B | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV57976041; called by muse, mutect2, varscan2
- FAM83E | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs543968839, COSV54372060; called by muse, mutect2, varscan2
- FAT4 | c.1019T>C p.L340P | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.762); catalogued as COSV67883305; called by muse, mutect2
- FBL | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); catalogued as COSV99695302; called by muse, mutect2, varscan2
- FBXO10 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs371540716; called by muse, mutect2, varscan2
- FCAMR | c.196dup p.R66Kfs*103 | Frame Shift Ins (INS) | VAF 34/116 reads (29%) | catalogued as rs750132652; called by mutect2, pindel, varscan2
- FCER2 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as rs777512868, COSV60917742; called by muse, mutect2, varscan2
- FCMR | c.450G>A p.M150I | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV65569740; called by muse, mutect2, varscan2
- FGD6 | c.1367C>A p.P456H | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.145); catalogued as COSV59697597; called by muse, mutect2, varscan2
- FGF10 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52940341; called by muse, mutect2, varscan2
- FGF2 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 145/348 reads (42%) | catalogued as COSV52648737; called by muse, mutect2, varscan2
- FGF23 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV52976418; called by muse, mutect2, varscan2
- FGFR1 | c.2383G>A p.V795I (on ENST00000447712 / NM_023110.3; = p.V793I on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs781328162, CM063983, COSV58345703; called by muse, mutect2, varscan2
- FGL2 | c.1103C>A p.S368Y | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as COSV50386323; called by muse, mutect2, varscan2
- FMN2 | c.1351C>A p.L451M | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV60457256; called by muse, varscan2
- FN1 | c.6959C>T p.T2320I (on ENST00000359671 / NM_001365524.2; = p.T2289I on NM_002026.4) | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV60565507; called by muse, mutect2, varscan2
- FOXP2 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 97/215 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV63494922; called by muse, mutect2, varscan2
- FREM1 | c.3958C>A p.Q1320K | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV66531248; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 31/94 reads (33%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FUCA1 | c.863T>G p.L288W | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs758328076, COSV65699696; called by muse, varscan2
- FZD2 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV59528462; called by muse, mutect2, varscan2
- FZR1 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58054255; called by muse, mutect2, varscan2
- GAA | c.2332G>A p.V778M | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as COSV100163223; called by muse, mutect2, varscan2
- GAB2 | c.1072C>T p.P358S (on ENST00000361507 / NM_080491.3; = p.P320S on NM_012296.3) | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.996); catalogued as COSV100416525; called by muse, mutect2, varscan2
- GALNT13 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs751205543, COSV67222006; called by muse, mutect2, varscan2
- GALNT17 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs200447325, COSV61185463; called by muse, mutect2
- GALT | c.566T>C p.V189A | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV66593627; called by muse, mutect2, varscan2
- GATAD2A | c.1094dup p.P366Tfs*74 | Frame Shift Ins (INS) | VAF 31/77 reads (40%) | catalogued as rs35804366; called by mutect2, pindel, varscan2
- GBP1 | c.1172del p.K391Sfs*28 | Frame Shift Del (DEL) | VAF 85/422 reads (20%) | catalogued as rs777277713; called by mutect2, varscan2
- GBX2 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 40/70 reads (57%) | catalogued as COSV60445894; called by muse, mutect2, varscan2
- GCAT | c.874T>C p.Y292H | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99959801; called by muse, mutect2, varscan2
- GCN1 | c.2804A>G p.D935G | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56115606; called by muse, mutect2, varscan2
- GCNA | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 239/536 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV65468486; called by muse, mutect2, varscan2
- GET1 | c.371_373del p.Y124del | In Frame Del (DEL) | VAF 68/206 reads (33%) | catalogued as rs769047232; called by pindel, varscan2
- GIMAP7 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs769675039, COSV57960941; called by muse, mutect2, varscan2
- GJD4 | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as COSV58703547; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 78/175 reads (45%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLI2 | c.3930C>G p.H1310Q (on ENST00000361492 / NM_001374353.1; = p.H1327Q on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.087); catalogued as COSV58052575; called by muse, mutect2, varscan2
- GMIP | c.1328-2A>G p.X443_splice | Splice Site (SNP) | VAF 32/72 reads (44%) | catalogued as COSV52560310; called by muse, mutect2
- GOLGA3 | c.3238C>T p.R1080W | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1260001304, COSV52645421; called by muse, mutect2, varscan2
- GOLPH3 | c.311A>C p.Q104P | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV54062859; called by muse, mutect2, varscan2
- GOT2 | c.273T>A p.N91K | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV55332345; called by muse, mutect2, varscan2
- GPATCH1 | c.2764C>T p.R922W | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs781557121, COSV50129666; called by muse, mutect2, varscan2
- GPR101 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs1221298957, COSV99981432; called by muse, mutect2, varscan2
- GPR21 | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.116); catalogued as rs542409705, COSV65379253; called by muse, mutect2, varscan2
- GPR68 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1334142767, COSV99473475; called by muse, mutect2, varscan2
- GPRC5D | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs76933056, COSV57433598; called by muse, mutect2, varscan2
- GPX1 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV69043783; called by muse, mutect2, varscan2
- GRIA2 | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 94/273 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.293); catalogued as COSV52408392; called by muse, mutect2, varscan2
- GRIK4 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as rs200724152; called by muse, mutect2, varscan2
- GRIN2D | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); catalogued as rs752367785, COSV54379307; called by mutect2, varscan2
- GRM3 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); catalogued as COSV64467970, COSV64480597; called by muse, mutect2, varscan2
- GRM6 | c.1615C>T p.H539Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.403); catalogued as rs1380815515, COSV99179628; called by mutect2, varscan2
- GRM7 | c.1580G>A p.C527Y | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63174685; called by muse, mutect2, varscan2
- GSAP | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs754726153, COSV57533692; called by muse, mutect2, varscan2
- GSX1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57233846; called by muse, mutect2, varscan2
- GTF3C1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs144027406; called by muse, mutect2, varscan2
- GUCY2D | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV54699299; called by muse, mutect2, varscan2
- HBEGF | c.473A>G p.D158G | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV50183521; called by muse, mutect2, varscan2
- HCN4 | c.2483G>A p.R828Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as rs747348560, COSV56088134; called by muse, mutect2, varscan2
- HCN4 | c.2056G>A p.V686M | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs550848544, COSV56088606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HECTD4 | c.3401G>A p.R1134H | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1317187989, COSV61178017; called by muse, mutect2, varscan2
- HEXIM2 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs760708659, COSV56235817; called by muse, mutect2, varscan2
- HIRA | c.359A>G p.Q120R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV54280627; called by muse, mutect2
- HNF1A | c.1163G>A p.S388N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV57467599; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.7-3del | Splice Region (DEL) | VAF 29/120 reads (24%) | catalogued as rs759915055; called by pindel, varscan2
- HNRNPH3 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as COSV56261175; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 30/56 reads (54%) | catalogued as rs767148651; called by mutect2, varscan2
- HNRNPUL2 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 123/300 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53666859; called by muse, mutect2, varscan2
- HOXA1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV56067952; called by muse, mutect2, varscan2
- HOXC4 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100324171; called by muse, mutect2, varscan2
- HOXD3 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1040288320, COSV50886041; called by muse, mutect2, varscan2
- HPN | c.112G>C p.A38P | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV99385106; called by muse, mutect2, varscan2
- HSD17B14 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as rs772197700, COSV54363376; called by muse, mutect2, varscan2
- HSD3B1 | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs1195963729, COSV99347950; called by muse, mutect2, varscan2
- HSP90AA1 | c.2128G>T p.A710S | Missense Mutation (SNP) | VAF 91/242 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV53491627; called by muse, mutect2, varscan2
- HSPA13 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 101/245 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs140867763, COSV53465090; called by muse, mutect2, varscan2
- HSPA2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV55971455; called by muse, mutect2, varscan2
- HSPA2 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.013); catalogued as COSV55971465; called by muse, mutect2, varscan2
- HSPD1 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 186/439 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs751104797, COSV61445089; called by mutect2, varscan2
- HTR1A | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV60500357; called by muse, mutect2, varscan2
- HTR2C | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 201/482 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781872799, COSV52221051, COSV52226263; called by muse, mutect2, varscan2
- HYDIN | c.13484A>G p.K4495R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.496); catalogued as COSV101125091; called by muse, mutect2, varscan2
- IFITM1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV60250106; called by muse, mutect2, varscan2
- IGDCC4 | c.2988_2989insCG p.G997Rfs*74 | Frame Shift Ins (INS) | VAF 11/31 reads (35%) | catalogued as COSV61539554; called by mutect2, pindel, varscan2
- IGF1R | c.3616G>A p.A1206T | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.389); catalogued as rs772355972, COSV51269233; called by muse, mutect2, varscan2
- IGFN1 | c.3406del p.R1136Gfs*8 (on ENST00000295591 / NM_001367841.1; = p.R3593Gfs*8 on NM_001164586.2) | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs774748743; called by mutect2, pindel, varscan2
- IGHM | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs772304630; called by muse, mutect2, varscan2
- IGLV1-47 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.207); catalogued as rs1450260678; called by muse, mutect2
- IGSF10 | c.5660T>C p.L1887S | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV56792673; called by muse, mutect2, varscan2
- IGSF9B | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs370647370; called by muse, mutect2, varscan2
- IL31 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 40/330 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100986571; called by muse, mutect2, varscan2
- IL4I1 | c.14-2A>G p.X5_splice | Splice Site (SNP) | VAF 70/167 reads (42%) | catalogued as COSV100352080; called by muse, mutect2, varscan2
- IMPG1 | c.148A>T p.K50* | Nonsense Mutation (SNP) | VAF 280/670 reads (42%) | catalogued as COSV64062446; called by muse, mutect2, varscan2
- INHBA | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99637730; called by muse, mutect2
- INSL6 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67563580; called by muse, mutect2, varscan2
- INTS13 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 186/461 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.284); catalogued as rs903228594, COSV53905864; called by muse, mutect2, varscan2
- INTS4 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 137/308 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as rs761630699, COSV59018071; called by muse, mutect2, varscan2
- IPO8 | c.3073C>A p.L1025I | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99805347; called by muse, mutect2, varscan2
- IQCD | c.1139G>A p.R380Q (on ENST00000416617 / NM_001330452.2; = p.R278Q on NM_138451.3) | Missense Mutation (SNP) | VAF 85/160 reads (53%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs773770700, COSV100232382, COSV55322886; called by muse, mutect2, varscan2
- IQSEC3 | c.2664G>T p.Q888H (on ENST00000538872 / NM_001170738.2; = p.Q585H on NM_015232.1) | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV58291857; called by muse, mutect2, varscan2
- IRS4 | c.2998C>A p.L1000I | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1354013285, COSV64535388, COSV64536266; called by muse, mutect2, varscan2
- ITGAX | c.2617G>A p.G873S | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs746609066, COSV99191727; called by muse, mutect2, varscan2
- ITGB3 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs147782061, CM061070; called by muse, mutect2, varscan2
- ITGB4 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as rs762334700, COSV52321367; called by muse, varscan2
- ITGB5 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1467398756, COSV56153596; called by muse, mutect2, varscan2
- ITPKA | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV53029543; called by muse, mutect2, varscan2
- ITPR1 | c.7987G>A p.V2663M (on ENST00000354582; = p.V2608M on NM_002222.7) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1428890136, COSV56968455, COSV56977527; called by muse, mutect2, varscan2
- JAK1 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as rs375122732, COSV100691751; called by muse, mutect2, varscan2
- JARID2 | c.2399A>G p.E800G | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs781115380, COSV59198637, COSV59199234; called by muse, mutect2, varscan2
- KANSL1 | c.800del p.K267Sfs*12 | Frame Shift Del (DEL) | VAF 67/330 reads (20%) | catalogued as COSV52273004; called by mutect2, pindel, varscan2
- KAT2B | c.1525A>G p.K509E | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as COSV55435306; called by muse, mutect2
- KAT6A | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs748450137, COSV55903002; called by muse, mutect2, varscan2
- KCNC4 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV63926801; called by muse, mutect2, varscan2
- KCND2 | c.1609del p.T537Lfs*40 | Frame Shift Del (DEL) | VAF 69/201 reads (34%) | catalogued as rs770990872; called by mutect2, pindel, varscan2
- KCNG2 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 187/328 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763117510, COSV60270771; called by muse, mutect2, varscan2
- KCNQ1 | c.710G>T p.R237M | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50135587; called by muse, mutect2, varscan2
- KCNV1 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV52086753, COSV52088893; called by muse, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 59/157 reads (38%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KDM3B | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs539384678, COSV58696020; called by muse, mutect2, varscan2
- KDM6B | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs756544042, COSV54687850; called by muse, mutect2, varscan2
- KIF23 | c.2416C>T p.R806C (on ENST00000260363; = p.R702C on NM_004856.7) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV52983357; called by muse, mutect2, varscan2
- KIF24 | c.3109C>T p.Q1037* | Nonsense Mutation (SNP) | VAF 55/122 reads (45%) | catalogued as COSV52659139; called by muse, mutect2, varscan2
- KIF26A | c.3440del p.P1147Lfs*101 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | catalogued as rs771825279; called by mutect2, pindel, varscan2
- KIF26B | c.2303T>C p.M768T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV63653556; called by muse, mutect2
- KIF3C | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53102451; called by muse, mutect2, varscan2
- KIF5B | c.1629G>A p.M543I | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV56651072, COSV56655886; called by muse, mutect2, varscan2
- KIF9 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.305); catalogued as rs1407738082, COSV55524000; called by muse, mutect2, varscan2
- KLF10 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as rs757650416, COSV53436978; called by muse, mutect2, varscan2
- KLF4 | c.1246C>T p.H416Y | Missense Mutation (SNP) | VAF 133/338 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65929675; called by muse, mutect2, varscan2
- KLHL34 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV65280396; called by muse, mutect2, varscan2
- KLHL35 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.321); catalogued as COSV100888776; called by muse, mutect2
- KLHL6 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV58069831; called by muse, mutect2, varscan2
- KMT2A | c.5291G>A p.R1764H | Missense Mutation (SNP) | VAF 168/449 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1555043444, COSV63282001; called by muse, mutect2, varscan2
- KMT2B | c.1656dup p.K553Qfs*46 | Frame Shift Ins (INS) | VAF 17/41 reads (41%) | catalogued as rs775294431; called by mutect2, varscan2
- KMT2B | c.4790G>A p.R1597Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55862380; called by muse, mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 7/19 reads (37%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- KMT2D | c.6397G>A p.A2133T | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); catalogued as rs781460562, COSV56439361; called by muse, varscan2
- KMT2D | c.5818C>A p.P1940T | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV56492263; called by muse, mutect2, varscan2
- KNDC1 | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV58847370; called by muse, mutect2, varscan2
- KRT28 | c.1184A>C p.D395A | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV60686497, COSV60686688; called by muse, mutect2, varscan2
- KRT7 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs1410509540, COSV59331347; called by muse, mutect2, varscan2
- KRTAP1-1 | c.396del p.C133Afs*4 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | catalogued as rs767482453; called by mutect2, pindel, varscan2
- KSR2 | c.2678del p.N893Tfs*116 | Frame Shift Del (DEL) | VAF 195/525 reads (37%) | catalogued as COSV56667073; called by mutect2, pindel, varscan2
- KSR2 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 90/187 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV60396422; called by muse, varscan2
- KTN1 | c.3302dup p.A1102Gfs*15 (on ENST00000395314 / NM_001271014.2; = p.A1073Gfs*15 on NM_004986.4) | Frame Shift Ins (INS) | VAF 108/255 reads (42%) | catalogued as rs1438655793; called by mutect2, varscan2
- LAMA1 | c.6314T>C p.L2105S | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67545147; called by muse, mutect2
- LAMA3 | c.2356C>A p.R786S | Missense Mutation (SNP) | VAF 94/271 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as COSV58082310, COSV58084586; called by muse, mutect2, varscan2
- LAMA3 | c.9530G>A p.G3177E (on ENST00000313654 / NM_198129.4; = p.G1568E on NM_000227.6) | Missense Mutation (SNP) | VAF 106/332 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as rs1373839972, COSV99334882; called by muse, varscan2
- LAMA5 | c.4487G>A p.G1496D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53374001; called by muse, mutect2, varscan2
- LAMA5 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as rs1289606137, COSV53374016; called by muse, mutect2, varscan2
- LAMC2 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs147781376; called by muse, mutect2, varscan2
- LAT2 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369438020; called by muse, mutect2, varscan2
- LCOR | c.3026C>T p.P1009L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV53718859; called by muse, mutect2, varscan2
- LETM1 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1373146076, COSV100245461; called by muse, mutect2, varscan2
- LGR4 | c.592A>G p.T198A | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV101004206; called by muse, mutect2, varscan2
- LGR4 | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV64866525; called by muse, mutect2, varscan2
- LIG1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as rs750475498, COSV54396512; called by muse, mutect2, varscan2
- LINGO1 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1244229848, COSV62438801; called by muse, mutect2, varscan2
- LMBR1L | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as rs747428015, COSV57269398, COSV57269546; called by muse, mutect2, varscan2
- LMTK3 | c.3085C>T p.P1029S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV54317764; called by muse, varscan2
- LOXL4 | c.2101C>T p.P701S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs890858839, COSV53259644; called by muse, mutect2, varscan2
- LPAR1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as rs778252713, COSV100730761; called by muse, mutect2, varscan2
- LPIN1 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.186); catalogued as rs757466722, COSV56771721; called by muse, mutect2, varscan2
- LRFN3 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.065); catalogued as COSV55816811; called by muse, mutect2
- LRP1B | c.12539C>T p.A4180V | Missense Mutation (SNP) | VAF 106/282 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99069008; called by muse, varscan2
- LRP4 | c.1123dup p.A375Gfs*24 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | catalogued as rs777522999; called by pindel, varscan2
- LRRK1 | c.4445C>T p.P1482L | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99440241; called by muse, mutect2, varscan2
- LUC7L3 | c.1165dup p.S389Kfs*2 | Frame Shift Ins (INS) | VAF 86/244 reads (35%) | catalogued as rs1229438198; called by mutect2, varscan2
- LZTS3 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.94); catalogued as rs759999966, COSV61277364; called by muse, mutect2, varscan2
- MACF1 | c.20786G>A p.R6929H (on ENST00000372915; = p.R4974H on NM_012090.5) | Missense Mutation (SNP) | VAF 121/291 reads (42%) | catalogued as rs183077332, COSV57147586; called by muse, mutect2, varscan2
- MAEA | c.746C>T p.T249M (on ENST00000303400 / NM_001017405.3; = p.T208M on NM_005882.5) | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1560386160, COSV53264531, COSV53265139; called by muse, mutect2, varscan2
- MAGEL2 | c.3610C>T p.L1204F | Missense Mutation (SNP) | VAF 109/212 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100045954; called by muse, mutect2, varscan2
- MAGI1 | c.3932G>A p.R1311H | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.407); catalogued as COSV58347461; called by muse, mutect2, varscan2
- MAN2A2 | c.1582del p.X528_splice | Splice Site (DEL) | VAF 16/49 reads (33%) | catalogued as rs1219552862; called by mutect2, pindel, varscan2
- MAN2A2 | c.2493dup p.V832Rfs*6 | Frame Shift Ins (INS) | VAF 63/182 reads (35%) | catalogued as rs755100936; called by mutect2, pindel, varscan2
- MAP1B | c.4065A>C p.K1355N | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99702407; called by muse, mutect2, varscan2
- MAP2K4 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267604739, COSV62256985; called by muse, mutect2, varscan2
- MAP7D1 | c.68dup p.E24Rfs*9 | Frame Shift Ins (INS) | VAF 40/120 reads (33%) | catalogued as rs761388884; called by mutect2, varscan2
- MAPK4 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.927); catalogued as COSV68544139; called by muse, mutect2, varscan2
- MAPKAPK5 | c.1279C>T p.R427W (on ENST00000551404 / NM_139078.3; = p.R425W on NM_003668.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs753238884, COSV73436153; called by muse, mutect2, varscan2
- MARK4 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1391975984, COSV53461791; called by muse, varscan2
- MARS1 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV56259187; called by muse, mutect2, varscan2
- MAST2 | c.3820del p.R1274Dfs*9 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | catalogued as rs1405419593; called by mutect2, pindel, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 39/114 reads (34%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MDGA1 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51791357; called by muse, mutect2, varscan2
- MDH1B | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs369119966; called by muse, varscan2
- MDM1 | c.712T>C p.F238L | Missense Mutation (SNP) | VAF 218/617 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs112211234, COSV57447773, COSV57449160; called by muse, mutect2, varscan2
- MED30 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52066409; called by muse, mutect2, varscan2
- MEGF8 | c.5007del p.T1670Qfs*60 (on ENST00000251268 / NM_001271938.2; = p.T1603Qfs*60 on NM_001410.3) | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as COSV99233906; called by mutect2, varscan2
- MELTF | c.1092del p.Y365Tfs*54 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | catalogued as rs748010566; called by mutect2, pindel, varscan2
- MIDEAS | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1208073504, COSV54099666; called by muse, mutect2, varscan2
- MINK1 | c.3596A>G p.D1199G | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99544967; called by muse, mutect2, varscan2
- MKNK1 | c.1165T>C p.F389L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100361274; called by muse, mutect2, varscan2
- MMEL1 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs776984984, COSV56526865; called by muse, mutect2, varscan2
- MMP21 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.609); catalogued as COSV64289228; called by muse, mutect2, varscan2
- MMRN2 | c.2374C>T p.R792W | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs1292543261, COSV100922568; called by muse, mutect2, varscan2
- MMUT | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 183/253 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51286401; called by muse, varscan2
- MPRIP | c.1534A>G p.T512A | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs555403048, COSV100505747; called by muse, mutect2, varscan2
- MPV17L | c.457G>A p.A153T (on ENST00000396385 / NM_001128423.2; = p.R129H on NM_173803.4) | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757414085, COSV55009252; called by muse, mutect2, varscan2
- MREG | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV54376080; called by muse, mutect2, varscan2
- MRPL57 | c.151A>G p.M51V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV53437437; called by muse, mutect2
- MRTFA | c.2659dup p.L887Pfs*10 | Frame Shift Ins (INS) | VAF 49/115 reads (43%) | catalogued as rs1359717938; called by mutect2, pindel, varscan2
- MST1R | c.2264del p.G755Vfs*19 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs1407832113; called by mutect2, pindel, varscan2
- MTCL1 | c.4960C>T p.R1654C (on ENST00000306329 / NM_001378206.1; = p.R1335C on NM_015210.4) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763181044, COSV60412669; called by muse, mutect2, varscan2
- MTFR1L | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1367185429, COSV65353493; called by muse, mutect2
- MTMR12 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as rs145436150; called by muse, mutect2, varscan2
- MTMR6 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.161); catalogued as COSV67809996; called by muse, mutect2, varscan2
- MUC2 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated, low confidence (0.52); catalogued as rs546395242; called by muse, mutect2, varscan2
- MUC4 | c.2383T>C p.S795P | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.316); catalogued as COSV100640569; called by muse, mutect2, varscan2
- MUC4 | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 210/565 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.966); catalogued as COSV62203076; called by muse, mutect2, varscan2
- MXRA5 | c.2167T>C p.F723L | Missense Mutation (SNP) | VAF 118/291 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54252888; called by muse, mutect2, varscan2
- MYBPC3 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs730880630, COSV57023040; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYH11 | c.5594C>T p.A1865V | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as rs1197566728, COSV55572256; called by muse, mutect2, varscan2
- MYH9 | c.5546T>C p.L1849P | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV53394175; called by muse, mutect2
- MYH9 | c.3914C>T p.A1305V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs141904682; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO18B | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs768072435, COSV59130698; called by muse, mutect2, varscan2
- MYO1F | c.251del p.P84Rfs*145 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as CM090125, COSV100596545, COSV57792734; called by mutect2, pindel, varscan2
- MYO7A | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV101289141; called by muse, mutect2, varscan2
- MYO9B | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748481095, COSV68279857; called by muse, mutect2, varscan2
- MYRIP | c.1189A>C p.S397R | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56883691; called by muse, mutect2
- NAA35 | c.1700del p.K567Rfs*6 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs770577267; called by mutect2, varscan2
- NAP1L2 | c.948T>A p.D316E | Missense Mutation (SNP) | VAF 92/202 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.456); catalogued as COSV65173158; called by muse, mutect2, varscan2
- NAV2 | c.2105C>A p.S702Y (on ENST00000396087 / NM_001244963.2; = p.S679Y on NM_145117.5) | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV62337177; called by muse, mutect2, varscan2
- NAXE | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV58041729; called by muse, mutect2, varscan2
- NBEA | c.389T>A p.V130E | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.367); catalogued as COSV100080473; called by muse, mutect2, varscan2
- NCAPD3 | c.4307G>A p.R1436Q | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs890752834, COSV54457570; called by muse, mutect2, varscan2
- NCF1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs1554413130, COSV99194284; called by muse, mutect2
- NCKIPSD | c.172-3del | Splice Region (DEL) | VAF 6/22 reads (27%) | catalogued as rs768132931; called by mutect2, varscan2
- NCLN | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV55743831; called by muse, mutect2, varscan2
- NCOA7 | c.209del p.K70Rfs*7 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs749319230; called by mutect2, varscan2
- NEFL | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV55337980; called by muse, mutect2
- NEO1 | c.1868A>G p.D623G | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV56078917; called by muse, mutect2, varscan2
- NETO1 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs766917390, COSV55016294; called by muse, mutect2, varscan2
- NEURL4 | c.3707A>T p.N1236I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV59753640; called by muse, mutect2, varscan2
- NEXN | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 211/557 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53944879; called by muse, mutect2, varscan2
- NFKB2 | c.2350G>A p.G784R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs367889547, COSV99192738; ClinVar: likely benign; called by muse, mutect2, varscan2
- NHS | c.3344C>T p.T1115M | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as rs763238998, COSV66283803; called by muse, mutect2, varscan2
- NKX2-1 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV61390438; called by muse, mutect2
- NLGN1 | c.1391A>G p.Q464R | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849396; called by muse, mutect2
- NLGN1 | c.2180A>C p.E727A | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.281); catalogued as COSV64348668; called by muse, mutect2, varscan2
- NLRP1 | c.2529-1G>T p.X843_splice | Splice Site (SNP) | VAF 26/46 reads (57%) | catalogued as COSV52580032; called by muse, mutect2, varscan2
- NLRP3 | c.1873C>A p.Q625K | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.474); catalogued as COSV60231908; called by muse, mutect2, varscan2
- NOL10 | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs761396603, COSV62043350; called by muse, mutect2, varscan2
- NOL6 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs776353162, COSV53046403; called by muse, mutect2, varscan2
- NOM1 | c.2009del p.L670Wfs*8 | Frame Shift Del (DEL) | VAF 91/203 reads (45%) | catalogued as rs752067057; called by mutect2, varscan2
- NOP2 | c.955A>C p.T319P (on ENST00000322166 / NM_001258308.2; = p.T315P on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs747540211, COSV100444945; called by muse, mutect2, varscan2
- NOX4 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs768559870, COSV54466141; called by muse, mutect2, varscan2
- NPHP3 | c.3125+2_3125+5del p.X1042_splice | Splice Site (DEL) | VAF 54/132 reads (41%) | catalogued as rs1560001975; called by pindel, varscan2
- NPR2 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 159/413 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV61315009; called by muse, mutect2, varscan2
- NR1H3 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs565653980, COSV68008944; called by muse, mutect2, varscan2
- NR3C2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs751757447, COSV61000850; called by muse, mutect2, varscan2
- NRK | c.1009del p.R337Dfs*8 | Frame Shift Del (DEL) | VAF 170/489 reads (35%) | catalogued as rs1336364406; called by mutect2, pindel, varscan2
- NRK | c.4645G>A p.G1549S | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV99687347, COSV99687891; called by muse, mutect2, varscan2
- NT5DC3 | c.1605dup p.T536Hfs*20 | Frame Shift Ins (INS) | VAF 31/95 reads (33%) | catalogued as rs1305029344; called by mutect2, pindel, varscan2
- NUAK1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 102/255 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs752539069, COSV54608942; called by muse, mutect2, varscan2
- NUDCD3 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs760773518, COSV58126643; called by muse, mutect2, varscan2
- NUDT7 | c.169T>C p.F57L | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as COSV99216083; called by muse, varscan2
- NUP214 | c.5545T>C p.S1849P | Missense Mutation (SNP) | VAF 89/722 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100845296; called by mutect2, varscan2
- NUTM1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs147118207; called by muse, mutect2, varscan2
- NYX | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1259178272, COSV100699415; called by muse, mutect2, varscan2
- OBSCN | c.16360G>A p.A5454T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1366719691, COSV52837247; called by muse, mutect2, varscan2
- ONECUT2 | c.552C>G p.H184Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs186386413, COSV72203247; called by muse, mutect2
- OPCML | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as COSV59425228; called by muse, mutect2, varscan2
- OR10G7 | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57868865, COSV57869120; called by muse, mutect2, varscan2
- OR10H5 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 81/175 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as rs371066167; called by muse, varscan2
- OR10P1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs377331592, COSV59008594; called by muse, mutect2, varscan2
- OR10X1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs144668774; called by muse, mutect2, varscan2
- OR14A16 | c.745C>T p.L249F | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as COSV100713775, COSV62926438; called by muse, mutect2, varscan2
- OR51B4 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 167/433 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV66517947; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs755413956; called by mutect2, varscan2
- OR51T1 | c.583T>C p.W195R | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.876); catalogued as COSV59028350; called by muse, mutect2, varscan2
- OR52B2 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73209680, COSV73209694; called by muse, mutect2, varscan2
- OR5AU1 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.95); PolyPhen benign (0.241); catalogued as COSV58616334; called by muse, mutect2, varscan2
- OSMR | c.2180C>T p.T727M | Missense Mutation (SNP) | VAF 125/335 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs544346899, COSV57092902; called by muse, mutect2, varscan2
- OTOF | c.3184G>A p.E1062K (on ENST00000272371 / NM_194248.3; = p.E315K on NM_004802.4) | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs767276475, COSV55503419; called by muse, mutect2, varscan2
- OTOGL | c.5183C>A p.P1728H (on ENST00000547103; = p.P1719H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 119/272 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV54024883; called by muse, mutect2, varscan2
- OXR1 | c.2257T>G p.Y753D (on ENST00000442977 / NM_001198532.1; = p.Y725D on NM_018002.3) | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52428029; called by muse, mutect2, varscan2
- P2RY13 | c.702del p.V235Yfs*81 | Frame Shift Del (DEL) | VAF 92/292 reads (32%) | catalogued as rs771457469; called by mutect2, pindel, varscan2
- PABPC3 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200568211, COSV55804412; called by muse, mutect2, varscan2
- PACSIN1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV55062742; called by muse, mutect2, varscan2
- PAK4 | c.565del p.Q189Sfs*180 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs1217359611; called by mutect2, varscan2
- PANK4 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.356); catalogued as rs370719786, COSV65866601; called by muse, mutect2, varscan2
- PARD3 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs768317108, COSV100401043; called by muse, varscan2
- PASD1 | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 96/256 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.02); catalogued as COSV64858150; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 36/101 reads (36%) | catalogued as CM011452; called by mutect2, varscan2
- PCBD1 | c.280A>G p.S94G | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as COSV54738832; called by muse, mutect2, varscan2
- PCBP2 | c.803T>C p.I268T | Missense Mutation (SNP) | VAF 141/275 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV63730138; called by muse, mutect2, varscan2
- PCDH17 | c.2182G>A p.V728I | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs1175788433, COSV64973001, COSV64980176; called by muse, mutect2, varscan2
- PCDH9 | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.709); catalogued as rs375314712, COSV100122556, COSV60525121; called by muse, mutect2, varscan2
- PCDHA12 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 102/238 reads (43%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as COSV56535192; called by muse, mutect2, varscan2
- PCDHA13 | c.2236G>T p.G746W | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56551195; called by muse, mutect2, varscan2
- PCDHA8 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as rs782454808, COSV100970763; called by muse, mutect2, varscan2
- PCDHB7 | c.1253A>G p.N418S | Missense Mutation (SNP) | VAF 77/231 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.928); catalogued as rs1554280148, COSV99176974; called by muse, mutect2, varscan2
- PCDHGA4 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53990858; called by muse, mutect2
- PCK1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs267606015, COSV60127421; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCLO | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 133/377 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV61672364; called by muse, mutect2, varscan2
- PCNX2 | c.2626G>A p.V876I | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs553389216, COSV50782205; called by muse, varscan2
- PCNX2 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs769363917, COSV50820130; called by muse, mutect2, varscan2
- PCNX3 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.987); catalogued as COSV100856414; called by muse, mutect2, varscan2
- PCTP | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 140/348 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52123988; called by muse, mutect2, varscan2
- PDCD11 | c.4589G>A p.R1530Q | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750487532, COSV53298137; called by muse, mutect2, varscan2
- PDCD6IP | c.362G>A p.S121N | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as COSV56246187; called by muse, mutect2, varscan2
- PDE12 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100239860; called by muse, varscan2
- PDZD7 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | catalogued as rs771163176, COSV64647807, COSV64648003, COSV99058718; called by muse, mutect2, varscan2
- PEAK1 | c.917C>A p.A306D | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56944395; called by muse, mutect2, varscan2
- PELI3 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs774879559, COSV57857068; called by muse, varscan2
- PER3 | c.3554C>T p.A1185V | Missense Mutation (SNP) | VAF 105/260 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1251112250, COSV100648472; called by muse, mutect2, varscan2
- PEX1 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV50422800; called by muse, varscan2
- PEX2 | c.589T>C p.W197R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63814384; called by muse, mutect2
- PFAS | c.2449G>A p.V817M | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs754015723, COSV58983807; called by muse, mutect2, varscan2
- PFKFB2 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 23/78 reads (29%) | PolyPhen possibly damaging (0.853); catalogued as rs779972554, COSV100892017, COSV65550034; called by muse, mutect2, varscan2
- PHKA2 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1321320267, COSV101177078, COSV101177544; called by muse, varscan2
- PHYHIP | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58689541; called by muse, mutect2, varscan2
- PIGO | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs375787674; called by muse, mutect2, varscan2
- PIK3C2B | c.3877C>A p.L1293M | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); catalogued as COSV65814602; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 24/68 reads (35%) | catalogued as rs749506841; called by mutect2, varscan2
- PIK3IP1 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs772737278, COSV53225056; called by muse, mutect2, varscan2
- PIP4K2A | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs763486152, COSV100114661, COSV60542894; called by muse, mutect2, varscan2
- PIP5KL1 | c.995T>C p.L332P (on ENST00000388747 / NM_001135219.2; = p.L129P on NM_173492.1) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100304860; called by muse, mutect2, varscan2
- PKD1 | c.8065C>T p.H2689Y | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs780697425, COSV99238185; called by muse, varscan2
- PKHD1L1 | c.5299A>C p.I1767L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.262); catalogued as COSV65754922; called by muse, mutect2, varscan2
- PKP1 | c.1607A>C p.N536T | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV55819850; called by muse, mutect2, varscan2
- PKP3 | c.1390del p.L464Sfs*183 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | catalogued as rs757594408; called by mutect2, pindel, varscan2
- PLCD1 | c.1332del p.L445Sfs*29 | Frame Shift Del (DEL) | VAF 31/93 reads (33%) | catalogued as rs1559371469; called by mutect2, pindel, varscan2
- PLCG1 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54824780; called by muse, mutect2, varscan2
- PLCG2 | c.624del p.K208Nfs*55 | Frame Shift Del (DEL) | VAF 39/128 reads (30%) | catalogued as rs1189737304; called by mutect2, pindel, varscan2
- PLCG2 | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV63875262, COSV63877423; called by muse, mutect2, varscan2
- PLCL1 | c.705C>G p.N235K | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV70879868; called by muse, mutect2, varscan2
- PLCL2 | c.2885C>T p.A962V (on ENST00000615277 / NM_001144382.2; = p.A836V on NM_015184.5) | Missense Mutation (SNP) | VAF 69/210 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.174); catalogued as rs775729111, COSV67625912; called by muse, mutect2, varscan2
- PLD1 | c.1421T>C p.V474A | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV100578177; called by muse, mutect2
- PLEC | c.7756C>T p.R2586W (on ENST00000322810 / NM_201380.4; = p.R2476W on NM_000445.5) | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as rs571406033, COSV100514423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA7 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs371698539; called by muse, mutect2, varscan2
- PLEKHG1 | c.3983G>A p.R1328H | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs754481715, COSV62045900; called by muse, mutect2, varscan2
- PLEKHG4B | c.13C>T p.R5W (on ENST00000283426; = p.R361W on NM_052909.5) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1039069776, COSV52056311; called by muse, mutect2
- PLEKHG5 | c.905G>A p.R302Q (on ENST00000400915 / NM_001042663.3; = p.R265Q on NM_020631.6) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.429); catalogued as rs1280977628, COSV61706451; called by muse, mutect2, varscan2
- PNLDC1 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.793); catalogued as rs1389140969, COSV99277448; called by muse, mutect2, varscan2
- PNMA8A | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV58139499; called by muse, mutect2, varscan2
- PODN | c.1723C>A p.L575M (on ENST00000395871; = p.L527M on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57016896; called by muse, mutect2, varscan2
- POGZ | c.3046del p.E1016Rfs*3 | Frame Shift Del (DEL) | VAF 47/136 reads (35%) | catalogued as COSV51852125; called by mutect2, pindel, varscan2
- POLG | c.3432G>T p.E1144D | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as COSV51525758; called by muse, mutect2, varscan2
- POLR2D | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 125/304 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV55759309; called by muse, mutect2, varscan2
- PPIL4 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99481671; called by muse, varscan2
- PPP1R16A | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 42/71 reads (59%) | catalogued as rs753682349, COSV52955065; called by muse, mutect2, varscan2
- PPP1R1B | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99566242; called by muse, mutect2, varscan2
- PPP6R2 | c.2561del p.P854Rfs*23 (on ENST00000216061 / NM_001365836.1; = p.P820Rfs*23 on NM_014678.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as COSV53291064; called by mutect2, pindel, varscan2
- PRAMEF12 | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 178/463 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.624); catalogued as COSV63216839; called by muse, mutect2
- PRDM1 | c.122T>C p.M41T | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV64850957; called by muse, mutect2
- PRDM9 | c.2150A>G p.E717G | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99690482; called by muse, mutect2, varscan2
- PRKCG | c.976T>C p.S326P | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99669030; called by mutect2, varscan2
- PROKR1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 92/243 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs200238619, COSV58137151; called by muse, mutect2, varscan2
- PRPF31 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756479054, COSV58087507; called by muse, mutect2, varscan2
- PRPF8 | c.4308G>A p.W1436* | Nonsense Mutation (SNP) | VAF 45/123 reads (37%) | catalogued as COSV100517513; called by muse, mutect2, varscan2
- PRR5 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs368755171, COSV99134373; called by muse, mutect2, varscan2
- PRR5L | c.781A>G p.S261G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100287063; called by muse, mutect2
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 37/126 reads (29%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- PRRX2 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.7); catalogued as rs766187907, COSV100991183; called by muse, mutect2, varscan2
- PRSS54 | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1034463095, COSV99540964; called by muse, mutect2, varscan2
- PSEN1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs149562759, CD962718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSEN2 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs149354305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTH2R | c.583T>G p.F195V | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99782489; called by muse, mutect2
- PTHLH | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 352/789 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs997861147, COSV52369760; called by muse, mutect2, varscan2
- PTK2 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61793738; called by muse, mutect2, varscan2
- PTOV1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs770938530, COSV55590931; called by muse, mutect2, varscan2
- PTPN13 | c.4604del p.K1535Sfs*16 (on ENST00000411767 / NM_080683.3; = p.K1516Sfs*16 on NM_006264.3) | Frame Shift Del (DEL) | VAF 67/209 reads (32%) | catalogued as rs1565531675; called by mutect2, pindel, varscan2
- PTPN3 | c.2698C>T p.R900C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs778066954, COSV52709882; called by muse, varscan2
- PTPRS | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs754224013, COSV53618208; called by muse, mutect2, varscan2
- PTPRU | c.3271C>T p.R1091C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760871118, COSV60537616; called by muse, mutect2, varscan2
- PXDNL | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs986221061, COSV62500022; called by muse, mutect2, varscan2
- PYGL | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs11541446; called by muse, mutect2, varscan2
- QRICH2 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 81/166 reads (49%) | catalogued as rs1387173818, COSV53158461; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1946del p.P649Rfs*111 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as COSV99241733; called by mutect2, pindel, varscan2
- RAB17 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1430132648, COSV99221310; called by muse, mutect2, varscan2
- RAB6C | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV101308509; called by mutect2, varscan2
- RAD54L2 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs532971546, COSV56577291; called by muse, varscan2
- RAI1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55399986; called by muse, mutect2, varscan2
- RALGAPB | c.4375C>T p.R1459W | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs929881882, COSV99485284; called by muse, mutect2, varscan2
- RALYL | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs553408971, COSV72826202; called by muse, mutect2, varscan2
- RANBP6 | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV52391841; called by muse, mutect2, varscan2
- RANGAP1 | c.293C>A p.P98Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs867682778, COSV100663770; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 90/215 reads (42%) | catalogued as COSV54590195; called by muse, mutect2, varscan2
- RASA1 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 108/239 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57194125; called by muse, mutect2, varscan2
- RASEF | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as COSV64588978; called by muse, mutect2, varscan2
- RASGEF1A | c.1334T>C p.I445T | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV65667602; called by muse, mutect2, varscan2
- RASGRF1 | c.2363C>T p.A788V | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV67251369; called by muse, mutect2, varscan2
- RBBP7 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV58112735; called by muse, mutect2, varscan2
- RBM15 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV63924629; called by muse, mutect2, varscan2
- RBM23 | c.727-2A>G p.X243_splice (on ENST00000359890 / NM_001077351.2; = p.X227_splice on NM_018107.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 129/351 reads (37%) | catalogued as COSV100321384; called by muse, mutect2, varscan2
- RBMXL2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs924901601, COSV60981988; called by muse, mutect2, varscan2
- RC3H1 | c.2844G>A p.M948I | Missense Mutation (SNP) | VAF 139/332 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV51221320; called by muse, mutect2, varscan2
- RCOR2 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56850516; called by muse, mutect2, varscan2
- RERE | c.3898C>T p.R1300C | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs774376666, COSV61952161; called by muse, mutect2, varscan2
- RESF1 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 76/181 reads (42%) | catalogued as COSV57026252; called by muse, mutect2, varscan2
- REV3L | c.5081del p.N1694Mfs*4 | Frame Shift Del (DEL) | VAF 52/278 reads (19%) | catalogued as COSV62617292; called by mutect2, pindel, varscan2
- RHPN1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs1442034169, COSV56649943; called by muse, mutect2, varscan2
- RICTOR | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 109/292 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs373647294; called by muse, mutect2, varscan2
- RIN3 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1363627007, COSV53656735; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 36/57 reads (63%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RLF | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.021); catalogued as COSV65653393; called by muse, mutect2, varscan2
- RNASEH2A | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.518); catalogued as COSV55552951; called by muse, mutect2, varscan2
- RNASEH2B | c.141A>C p.E47D | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100352326; called by muse, mutect2
- RNF133 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775016583, COSV57388760; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 34/63 reads (54%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROS1 | c.3500del p.L1167* | Frame Shift Del (DEL) | VAF 24/158 reads (15%) | catalogued as rs748436511; called by mutect2, varscan2
- RP1L1 | c.2965G>T p.G989C | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV101223271; called by muse, mutect2, varscan2
- RPA4 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV61294919; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 17/33 reads (52%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL7A | c.555G>T p.K185N | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV59300353; called by muse, mutect2, varscan2
- RPRD2 | c.4343C>T p.P1448L | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs373559731; called by muse, mutect2, varscan2
- RPS6KA5 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs1298075797, COSV56223481; called by muse, varscan2
- RPTOR | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV60819632; called by muse, mutect2, varscan2
- RPTOR | c.2989C>T p.R997C | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs201400170; called by muse, mutect2, varscan2
- RSBN1L | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 26/147 reads (18%) | catalogued as COSV58506918; called by muse, mutect2, varscan2
- RSKR | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 45/137 reads (33%) | catalogued as rs772747192, COSV56384276; called by muse, mutect2, varscan2
- RUNX1 | c.865G>A p.E289K (on ENST00000344691 / NM_001001890.3; = p.E316K on NM_001754.5) | Missense Mutation (SNP) | VAF 99/252 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.373); catalogued as COSV55874016; called by muse, mutect2, varscan2
- RXFP3 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.129); catalogued as COSV57507282; called by muse, mutect2, varscan2
- RYR1 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100615795; called by muse, mutect2, varscan2
- RYR1 | c.7551C>A p.F2517L | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.952); catalogued as COSV62112658; called by muse, mutect2, varscan2
- RYR1 | c.14008G>A p.V4670I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV62112663; called by muse, mutect2, varscan2
- RYR2 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs766420655, COSV63718535; called by mutect2, varscan2
- RYR2 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 240/644 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV63718543; called by muse, mutect2, varscan2
- S1PR4 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55740166; called by muse, mutect2, varscan2
- SAC3D1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs374748039; called by muse, mutect2, varscan2
- SAGE1 | c.1403C>A p.A468E | Missense Mutation (SNP) | VAF 139/340 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV61018787; called by muse, mutect2, varscan2
- SBSN | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 62/146 reads (42%) | catalogued as COSV71733368; called by muse, mutect2, varscan2
- SCARA3 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.261); catalogued as rs757129937, COSV57270029; called by muse, mutect2, varscan2
- SCARB1 | c.280T>C p.Y94H | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55553206; called by muse, mutect2, varscan2
- SCN8A | c.5711G>A p.R1904H | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs142069713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCPEP1 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99227858; called by muse, mutect2, varscan2
- SDHA | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs587782076, COSV53774309; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC31B | c.2057A>G p.Y686C | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64845126; called by muse, mutect2, varscan2
- SEPHS1 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 140/335 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV59257665; called by muse, mutect2, varscan2
- SERAC1 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 111/340 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV65598190; called by muse, varscan2
- SERPINA5 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61574911, COSV61575168; called by muse, mutect2
- SFTPA1 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 211/545 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.411); catalogued as rs876658000, COSV64867884; ClinVar: uncertain significance; called by muse, varscan2
- SGSH | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as rs780969693, COSV100413452; called by muse, mutect2, varscan2
- SH3BP5 | c.493A>G p.R165G | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV53746961; called by muse, mutect2, varscan2
- SHANK3 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757642421, COSV53191988; called by muse, mutect2, varscan2
- SHROOM2 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs764492293, COSV66607320; called by muse, mutect2, varscan2
- SHROOM3 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs758148359, COSV56023275; called by muse, mutect2, varscan2
- SHROOM3 | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs997724339, COSV56040746; called by muse, mutect2, varscan2
- SIGLEC1 | c.3769C>T p.R1257W | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs138190270; called by muse, mutect2, varscan2
- SIPA1 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs374792529; called by muse, mutect2, varscan2
- SIPA1L2 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV53401345; called by muse, mutect2, varscan2
- SLAIN1 | c.1574C>T p.S525L (on ENST00000466548; = p.S262L on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs544749290, COSV57387419, COSV99934893; called by muse, mutect2, varscan2
- SLAIN2 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs774856780, COSV51906703; called by muse, mutect2, varscan2
- SLC10A6 | c.806T>C p.M269T | Missense Mutation (SNP) | VAF 96/243 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV56723644; called by muse, mutect2
- SLC12A3 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369510226, CM116326; called by muse, mutect2, varscan2
- SLC16A9 | c.564G>A p.M188I | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68100895; called by muse, mutect2, varscan2
- SLC22A16 | c.1694C>T p.T565M | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs757260946, COSV57934754; called by muse, mutect2, varscan2
- SLC25A23 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs753656506, COSV51198731; called by muse, mutect2, varscan2
- SLC25A31 | c.767A>G p.E256G | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV99829452; called by muse, mutect2, varscan2
- SLC25A37 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99263975; called by muse, mutect2, varscan2
- SLC32A1 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99462255; called by muse, mutect2, varscan2
- SLC39A10 | c.342T>G p.I114M | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV62769925; called by muse, mutect2, varscan2
- SLC39A4 | c.697del p.V233Wfs*39 (on ENST00000301305 / NM_001374839.1; = p.V208Wfs*39 on NM_017767.3) | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs782519481; called by mutect2, pindel, varscan2
- SLC3A2 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1193174410, COSV58605160; called by muse, mutect2, varscan2
- SLC4A5 | c.3236del p.K1079Rfs*29 | Frame Shift Del (DEL) | VAF 112/411 reads (27%) | catalogued as rs778293501; called by pindel, varscan2
- SLC66A1 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 70/152 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs143243971, COSV64320854; called by muse, varscan2
693 further variants in this file (333 protein-altering or splice-affecting, 325 silent, 35 other) are not listed here.
